Somatic mutation profile of tumor specimen TCGA-RU-A8FL-01A (aliquot TCGA-RU-A8FL-01A-11D-A36X-10) from TCGA case TCGA-RU-A8FL, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 52.0 years (18,975 days).
Specimen TCGA-RU-A8FL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ea0a29a-8433-4299-81b7-278c2942aeda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RU-A8FL-10A (Blood Derived Normal), aliquot TCGA-RU-A8FL-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ca37c45-05a6-471f-8b64-849cadfba3b8

The open-access MAF lists 144 somatic variants for this specimen: 102 protein-altering or splice-affecting, 37 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 37, Nonsense Mutation 6, Intron 2, Frame Shift Del 2, Frame Shift Ins 2, 5'UTR 2, In Frame Ins 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 24/32 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABHD12 | c.905T>C p.L302P | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100194239; called by muse, mutect2, varscan2
- ADAMTS5 | c.1483C>A p.Q495K | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV53178891; called by muse, mutect2, varscan2
- ADGRB3 | c.660A>T p.L220F | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.969); catalogued as COSV65408142; called by muse, mutect2, varscan2
- AGO4 | c.1994G>A p.R665Q | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs1321354225, COSV100942745; called by muse, mutect2, varscan2
- AHNAK | c.11113G>A p.V3705M | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.297); catalogued as COSV99946011; called by muse, mutect2, varscan2
- AKAP9 | c.8456C>T p.P2819L (on ENST00000359028; = p.P2795L on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as COSV100662022; called by muse, mutect2
- ALKAL1 | c.301A>C p.T101P | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100660102; called by muse, mutect2, varscan2
- ANKRD11 | c.5540C>T p.S1847L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1294353692, COSV99968524; called by muse, mutect2, varscan2
- AP3B2 | c.2119A>T p.S707C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV99916143; called by muse, mutect2, varscan2
- APC | c.4467dup p.H1490Tfs*24 | Frame Shift Ins (INS) | VAF 21/100 reads (21%) | catalogued as COSV57328203, COSV57345161; called by mutect2, pindel, varscan2
- APPBP2 | c.1029C>A p.H343Q | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.692); catalogued as COSV50028146; called by muse, mutect2, varscan2
- BTG3 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100336244; called by muse, mutect2, varscan2
- CACUL1 | c.578G>C p.R193T | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100432444; called by muse, mutect2, varscan2
- CCR3 | c.914G>T p.G305V | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100656362, COSV62464152; called by muse, mutect2, varscan2
- CEP164 | c.1250G>A p.S417N | Missense Mutation (SNP) | VAF 65/121 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV54045953; called by muse, mutect2, varscan2
- CLDN18 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.983); catalogued as rs369029508, COSV59304518; called by muse, mutect2, varscan2
- COL12A1 | c.3943G>A p.D1315N | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as rs185615367; called by muse, mutect2, varscan2
- CPS1 | c.2440C>T p.R814W | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772782772, CM114355, COSV99242192; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- DGCR8 | c.1513A>G p.I505V | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as COSV100707839; called by muse, mutect2, varscan2
- DHX15 | c.24C>A p.D8E | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as COSV61028370; called by muse, mutect2, varscan2
- DNAH11 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.066); catalogued as COSV100177764; called by muse, mutect2, varscan2
- DOCK8 | c.5687C>G p.T1896S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.18); catalogued as COSV66622318; called by muse, mutect2, varscan2
- EFCAB7 | c.682G>T p.G228C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV100937604; called by muse, mutect2, varscan2
- EHBP1 | c.3517C>T p.R1173* | Nonsense Mutation (SNP) | VAF 48/116 reads (41%) | catalogued as COSV99860230; called by muse, mutect2, varscan2
- ELOVL1 | c.684G>C p.Q228H | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60522596, COSV60522814; called by muse, mutect2, varscan2
- FAM13C | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV53254285; called by muse, mutect2, varscan2
- FAM20A | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 12/195 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs1279417191, COSV101646487; called by muse, mutect2
- FAT2 | c.10764C>G p.I3588M | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99941939; called by muse, mutect2, varscan2
- FHL5 | c.546G>C p.W182C | Missense Mutation (SNP) | VAF 92/219 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1166630030, COSV100459204; called by muse, mutect2, varscan2
- FLNC | c.6829C>T p.R2277C | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs761696270, COSV100367705; called by muse, mutect2, varscan2
- FRYL | c.7483G>A p.A2495T | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.103); catalogued as rs757872294, COSV51939494; called by muse, mutect2, varscan2
- FZD10 | c.155T>C p.M52T | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99969281; called by muse, mutect2, varscan2
- GRID2 | c.2072T>C p.V691A | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as rs1194444077, COSV99938305; called by muse, mutect2, varscan2
- GTF2H5 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 19/105 reads (18%) | catalogued as COSV101659565, COSV101659572; called by muse, mutect2, varscan2
- H4C13 | c.56A>C p.H19P | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV100137735; called by muse, mutect2, varscan2
- HAS1 | c.1028C>T p.T343I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs765536727, COSV99708254; called by muse, mutect2, varscan2
- HMX2 | c.289G>C p.G97R | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV100378690; called by muse, mutect2, varscan2
- HTT | c.4255C>A p.H1419N | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as rs375899948; called by muse, mutect2, varscan2
- IGKV2-24 | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 84/234 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as rs780477989; called by muse, mutect2, varscan2
- IGLV3-9 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as rs747589489; called by muse, mutect2, varscan2
- IGSF6 | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.616); catalogued as COSV99193615; called by muse, mutect2, varscan2
- IRAK3 | c.200G>A p.S67N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54163865; called by muse, mutect2, varscan2
- IRS4 | c.1699G>A p.G567R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.963); catalogued as COSV100929462; called by muse, mutect2, varscan2
- ITIH2 | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as rs376208756; called by muse, mutect2, varscan2
- JMJD1C | c.5527C>T p.R1843W | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751030734, COSV59515668; called by muse, mutect2, varscan2
- JRK | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1554636031, COSV70629659; called by muse, mutect2, varscan2
- KRT34 | c.62G>C p.R21T | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as COSV101222514, COSV101222709; called by muse, mutect2, varscan2
- LAMA1 | c.5219T>C p.L1740P | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as COSV101055366; called by muse, mutect2, varscan2
- LMF1 | c.50G>A p.R17K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs754222774, COSV99234736; called by muse, mutect2, varscan2
- MCF2 | c.32T>C p.M11T | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100644544; called by muse, mutect2
- MIPOL1 | c.1124A>C p.N375T | Missense Mutation (SNP) | VAF 65/232 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as COSV100538217; called by muse, mutect2, varscan2
- MYO15A | c.5318A>T p.K1773M | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99231502; called by muse, mutect2, varscan2
- NEDD4L | c.2345T>A p.F782Y (on ENST00000400345 / NM_001144967.3; = p.F762Y on NM_015277.6) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); catalogued as COSV99893723; called by muse, mutect2, varscan2
- NEIL3 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762418261, COSV99220054; called by muse, mutect2, varscan2
- OR11H1 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 137/286 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs369991794, COSV99421499; called by muse, varscan2
- PAN2 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1183637507, COSV99228140; called by muse, mutect2, varscan2
- PCDHA9 | c.1705C>T p.R569W | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV65324208, COSV65330053; called by muse, mutect2, varscan2
- PEX5L | c.775A>T p.N259Y | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV99828138; called by muse, mutect2, varscan2
- PLEKHM3 | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs563426938, COSV66817744; called by muse, mutect2, varscan2
- PRKAA1 | c.656T>A p.L219* | Nonsense Mutation (SNP) | VAF 49/125 reads (39%) | catalogued as COSV99713115; called by muse, mutect2, varscan2
- PROS1 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs963668412, CM163572, CM951040, COSV62399187; called by muse, mutect2, varscan2
- PTPRU | c.2195G>A p.S732N | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.231); catalogued as COSV60532962; called by muse, mutect2, varscan2
- PYM1 | c.283_285del p.E95del | In Frame Del (DEL) | VAF 38/103 reads (37%) | catalogued as rs1221143409; called by mutect2, pindel, varscan2
- RAPGEF3 | c.635G>A p.G212E (on ENST00000389212; = p.G170E on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs746087369, COSV99405921; called by muse, mutect2, varscan2
- RASEF | c.2059T>C p.C687R | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64587958; called by muse, mutect2, varscan2
- REM1 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199660041, COSV52427586; called by muse, mutect2, varscan2
- RNF19A | c.562A>T p.I188F | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as CM162909, COSV100347448; called by muse, mutect2, varscan2
- RTN3 | c.648G>C p.E216D (on ENST00000377819 / NM_001265589.2; = p.E197D on NM_201428.3) | Missense Mutation (SNP) | VAF 57/97 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as COSV100127389; called by muse, mutect2, varscan2
- RXFP2 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs373570227; called by muse, mutect2, varscan2
- SASH1 | c.3437A>G p.D1146G | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100820963; called by muse, mutect2, varscan2
- SCD5 | c.884C>G p.T295S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as rs1341937975, COSV100124412; called by muse, mutect2
- SETMAR | c.1717C>G p.L573V | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.66); catalogued as rs372022724, COSV62781200; called by muse, mutect2, varscan2
- SIPA1L3 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99727615; called by muse, mutect2, varscan2
- SLC11A2 | c.382G>A p.V128M (on ENST00000394904 / NM_001379455.1; = p.V99M on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.149); catalogued as COSV100014512; called by muse, mutect2, varscan2
- SLC7A14 | c.271T>C p.F91L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99200390; called by muse, mutect2, varscan2
- SOX9 | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 87/211 reads (41%) | catalogued as COSV99818228; called by muse, mutect2, varscan2
- SP110 | c.1208C>G p.T403S | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as COSV99283131; called by muse, mutect2, varscan2
- SPAM1 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.073); catalogued as rs1262667071, COSV56141967; called by muse, mutect2, varscan2
- SPATA16 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); catalogued as rs200456888, COSV63529894; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STAM2 | c.1468T>C p.Y490H | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); catalogued as COSV99812898; called by muse, mutect2, varscan2
- STYK1 | c.824A>C p.E275A | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.758); catalogued as COSV99311643; called by muse, mutect2, varscan2
- TAFA5 | c.359C>T p.T120M (on ENST00000402357 / NM_001082967.3; = p.T113M on NM_015381.7) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as rs777359527, COSV100385462; called by muse, mutect2
- THBS1 | c.3495C>A p.Y1165* | Nonsense Mutation (SNP) | VAF 27/38 reads (71%) | catalogued as COSV99527645; called by muse, mutect2, varscan2
- TPR | c.6265G>A p.A2089T | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs760082912, COSV66603287; called by muse, mutect2, varscan2
- TRIM44 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.886); catalogued as COSV100194794; called by muse, mutect2, varscan2
- TUBB8 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.861); catalogued as rs781910790, COSV100225958; called by muse, mutect2, varscan2
- USP15 | c.1603G>A p.A535T (on ENST00000280377 / NM_001351159.2; = p.A506T on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs367863159, COSV54794689; called by muse, mutect2, varscan2
- VDAC2 | c.178A>G p.T60A | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100040830; called by muse, mutect2, varscan2
- VPS26C | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs766553233, COSV99898328; called by muse, mutect2, varscan2
- WTAP | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); catalogued as COSV100493268; called by muse, mutect2, varscan2
- XRN1 | c.4070G>A p.R1357Q | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs770978242, COSV53810924; called by muse, mutect2, varscan2
- ZFHX3 | c.2018G>T p.C673F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99195574; called by muse, mutect2, varscan2
- ZNF396 | c.628C>G p.L210V | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.088); catalogued as COSV60474686; called by muse, mutect2, varscan2
- ZNF599 | c.1714T>A p.F572I | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100251028; called by muse, mutect2, varscan2
- ZNF804A | c.3347_3358dup p.A1116_A1119dup | In Frame Ins (INS) | VAF 16/70 reads (23%) | catalogued as rs754346637; called by mutect2, varscan2
- ZNRF4 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771572851, COSV55776932; called by muse, mutect2, varscan2
- ZP4 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs371052672; called by muse, mutect2, varscan2
- AP3B1 | c.421dup p.S141Kfs*3 | Frame Shift Ins (INS) | VAF 39/91 reads (43%) | called by mutect2, pindel, varscan2
- EP400 | c.6212_6230del p.L2071Rfs*37 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | called by mutect2, pindel
- POLQ | c.7486del p.H2496Tfs*59 | Frame Shift Del (DEL) | VAF 18/164 reads (11%) | called by mutect2, pindel, varscan2
- AASDH | c.1353C>G p.G451= | Silent (SNP) | VAF 200/294 reads (68%) | catalogued as COSV99220929; called by muse, mutect2, varscan2
- AC097637.1 | c.324C>T p.G108= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs756643412, COSV59725845; called by muse, mutect2, varscan2
- AFF1 | c.1917C>T p.S639= | Silent (SNP) | VAF 31/41 reads (76%) | catalogued as COSV57122179; called by muse, mutect2, varscan2
- AKT3 | c.972C>G p.G324= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as COSV99794442, COSV99795689; called by muse, mutect2, varscan2
- APC2 | c.3444G>A p.S1148= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs760286752, COSV52020498; called by muse, mutect2, varscan2
- ARHGAP15 | c.147C>T p.V49= | Silent (SNP) | VAF 41/104 reads (39%) | catalogued as rs752676733, COSV99708991; called by muse, mutect2, varscan2
- C2CD3 | c.5712C>A p.L1904= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV58096567; called by muse, mutect2, varscan2
- CCM2L | c.195C>T p.V65= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV52951651; called by muse, mutect2, varscan2
- CDC42BPG | c.4545C>T p.S1515= | Silent (SNP) | VAF 32/53 reads (60%) | catalogued as rs771470342, COSV61347799; called by muse, mutect2, varscan2
- CPD | c.2673C>T p.T891= | Silent (SNP) | VAF 37/215 reads (17%) | catalogued as rs1567881005, COSV99852539; called by muse, mutect2, varscan2
- CSF2RA | c.807A>T p.L269= | Silent (SNP) | VAF 79/231 reads (34%) | catalogued as COSV62625869; called by mutect2, varscan2
- DDX21 | c.1203T>C p.G401= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV100826479; called by muse, mutect2, varscan2
- FBLN2 | c.768G>A p.A256= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs758662969, COSV99851516; called by muse, mutect2, varscan2
- FMN2 | c.2880C>A p.P960= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs745670012, COSV60425761, COSV60434225; called by muse, mutect2, varscan2
- FZD1 | c.534C>G p.T178= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs1425747728, COSV55312393; called by muse, mutect2, varscan2
- HTR1B | c.1092C>A p.I364= | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as COSV100885355; called by muse, mutect2, varscan2
- ITGA5 | c.900C>T p.Y300= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs559129448, COSV99516396; called by mutect2, varscan2
- KIT | c.2868G>A p.R956= | Silent (SNP) | VAF 77/108 reads (71%) | catalogued as COSV99853503; called by muse, mutect2, varscan2
- LCA5 | c.963C>T p.C321= | Silent (SNP) | VAF 63/127 reads (50%) | catalogued as COSV100878182; called by muse, mutect2, varscan2
- LHX8 | c.642C>G p.L214= | Silent (SNP) | VAF 19/191 reads (10%) | catalogued as COSV99633201; called by muse, mutect2, varscan2
- LTF | c.1086G>A p.A362= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs61740472; called by muse, mutect2, varscan2
- NCAM2 | c.558T>C p.C186= | Silent (SNP) | VAF 57/149 reads (38%) | catalogued as COSV99521709; called by muse, mutect2, varscan2
- NRCAM | c.1869C>T p.D623= (on ENST00000379028 / NM_001371124.1; = p.D617= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100694332; called by muse, mutect2, varscan2
- OBSCN | c.16785C>T p.G5595= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as rs369078292; called by muse, mutect2, varscan2
- OR2AG2 | c.147C>A p.I49= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV100643080; called by muse, mutect2, varscan2
- OR4K1 | c.279C>A p.S93= | Silent (SNP) | VAF 74/362 reads (20%) | catalogued as COSV53462524, COSV99578724; called by muse, mutect2
- OR5T3 | c.600T>C p.S200= | Silent (SNP) | VAF 85/216 reads (39%) | catalogued as COSV100282706, COSV57379270; called by muse, mutect2, varscan2
- PTPRZ1 | c.5815A>C p.R1939= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as COSV66441898; called by muse, mutect2
- RYR2 | c.12540C>T p.G4180= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs772125105, COSV63694292; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SGF29 | c.255G>A p.A85= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs1368062076, COSV100187054; called by muse, mutect2, varscan2
- SP140 | c.1416G>A p.T472= | Silent (SNP) | VAF 75/165 reads (45%) | catalogued as rs746712057, COSV59452762; called by muse, mutect2, varscan2
- SSTR4 | c.195C>T p.N65= | Silent (SNP) | VAF 42/63 reads (67%) | catalogued as COSV54797786; called by muse, mutect2, varscan2
- TNRC6B | c.3003C>T p.D1001= (on ENST00000454349 / NM_001162501.2; = p.D948= on NM_015088.3) | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs370055398; called by muse, mutect2, varscan2
- USP13 | c.867G>A p.A289= | Silent (SNP) | VAF 39/182 reads (21%) | catalogued as rs148480598; called by muse, mutect2, varscan2
- ZFAT | c.1960C>T p.L654= | Silent (SNP) | VAF 66/78 reads (85%) | catalogued as COSV64742517; called by muse, mutect2, varscan2
- ZMIZ1 | c.1305C>T p.N435= | Silent (SNP) | VAF 31/57 reads (54%) | catalogued as COSV100565940; called by muse, mutect2, varscan2
- ZNF835 | c.933C>T p.C311= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV73379544; called by muse, mutect2, varscan2
- ALKBH6 | c.-109T>G | 5'UTR (SNP) | VAF 7/24 reads (29%) | catalogued as COSV99430876; called by muse, mutect2, varscan2
- GAD2 | c.-2C>T | 5'UTR (SNP) | VAF 8/15 reads (53%) | catalogued as rs1171276341, COSV52152463; called by muse, mutect2, varscan2
- GULP1 | c.-172+4381T>G | Intron (SNP) | VAF 60/307 reads (20%) | catalogued as COSV100770297; called by muse, mutect2, varscan2
- HLA-L | n.670G>A | RNA (SNP) | VAF 17/81 reads (21%) | called by muse, mutect2, varscan2
- NIPAL3 | c.1021+1958G>T | Intron (SNP) | VAF 32/89 reads (36%) | catalogued as COSV99135167; called by muse, mutect2, varscan2
